Gene-level copy-number profile of tumor specimen TCGA-FD-A5C0-01A from TCGA case TCGA-FD-A5C0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.6 years (22,500 days).
Specimen TCGA-FD-A5C0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.321c21e9-c261-4c1f-937f-64f526195d3f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A5C0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7fd2147a-bcc3-4bb6-9269-22c04ddcf0ae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,917; copy number 2: 28,532; copy number 3: 15,477; copy number 4: 12,206; copy number 5: 43; copy number 6: 575; copy number 8: 23; copy number 9: 156; copy number 10: 427; copy number 11: 407; copy number 13: 21; copy number 15: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A5C0-01A-11D-A288-01): tumor purity 0.58, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,648 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–121,580,524, 80 genes, copy number 9 (broad region; genes not listed).
- chr1:147,258,885–156,248,117, 465 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:89,410,960–89,999,409, 9 genes, copy number 5 (within-gene range 4–5): AC093866.1, AC097478.4, SNCA, AC097478.1, AC097478.3, AC097478.2, SNCA-AS1, MMRN1, AC105445.1.
- chr16:34,962,970–35,912,516, 81 genes, copy number 11 (broad region; genes not listed).
- chr16:67,028,984–81,096,296, 427 genes, copy number 10 (within-gene range 1–10) (broad region; genes not listed).
- chr19:35,351,552–37,130,368, 109 genes, copy number 6 (broad region; genes not listed).
- chr19:37,128,679–37,141,640, 1 gene, copy number 6 (within-gene range 4–6): AC012309.2.
- chr21:10,328,411–21,543,329, 150 genes, copy number 8–15 (within-gene range 4–15) (broad region; genes not listed).
- chr21:35,713,139–46,445,769, 325 genes, copy number 11 (broad region; genes not listed).
- chr21:46,462,471–46,469,306, 1 gene, copy number 11: DIP2A-IT1.

Autosomal genes at a single copy (total copy number 1): 1,917. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
